Gene-level copy-number profile of tumor specimen HCM-BROD-1121-C71-01A from HCMI case HCM-BROD-1121-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.5 years (25,400 days).
Specimen HCM-BROD-1121-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 08631103-8399-43d7-a09f-4699c3a3a04d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-1121-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/68c51727-6b57-4582-b6be-8d25e8010ac4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,020; copy number 2: 48,714; copy number 3: 5,658; copy number 4: 4; copy number 5: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:18,450,244–18,494,945, 5 genes, copy number 5: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C.

Autosomal genes at a single copy (total copy number 1): 4,020. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
